Gene-level copy-number profile of tumor specimen TCGA-IR-A3LA-01A from TCGA case TCGA-IR-A3LA, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 60.1 years (21,949 days).
Specimen TCGA-IR-A3LA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.b527188b-4601-4037-ab58-c5f4e21602aa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IR-A3LA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/571efefa-9341-4112-9934-a32230b96cc7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,200; copy number 2: 45,298; copy number 3: 5,223; copy number 4: 2,652; copy number 5: 704; copy number 6: 673; copy number 8: 4; copy number 9: 46; copy number 17: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IR-A3LA-01A-11D-A22W-01): tumor purity 0.88, ploidy 2.13, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,422 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:68,330,955–68,852,763, 4 genes, copy number 5 (within-gene range 3–5): C8orf34, RPS15AP25, RNA5SP269, AC083967.1.
- chr8:76,162,119–103,415,189, 469 genes, copy number 6 (broad region; genes not listed).
- chr8:103,414,714–103,443,453, 1 gene, copy number 6 (within-gene range 4–6): DCAF13.
- chr11:66,744,451–66,843,516, 1 gene, copy number 6 (within-gene range 3–6): C11orf80.
- chr11:66,842,835–70,207,390, 131 genes, copy number 6–17 (broad region; genes not listed).
- chr11:70,278,921–70,279,297, 1 gene, copy number 9: H2AZP4.
- chr11:70,283,955–70,284,070, 1 gene, copy number 9: MIR548K.
- chr15:96,756,987–99,105,824, 39 genes, copy number 5 (within-gene range 4–5): FAM149B1P1, SPATA8-AS1, SPATA8, RN7SKP181, LINC02253, AC020704.1, LINC02254, RN7SL677P, RNA5SP401, AC026523.2, AC026523.1, AC026523.3, AC026523.4, LINC00923, AC024651.2, AC024651.3, ARRDC4, AC024651.1, LINC02251, U6, AC022523.1, RNU6-1186P, LINC01582, AC022523.3, AC022523.2, AC015722.1, AC015722.2, LINC02351, FAM169B, AC103968.1, IRAIN, IGF1R, AC118658.1, MIR4714, AC055807.1, AC069029.1, AC036108.1, PGPEP1L, LUNAR1.
- chr18:22,413,599–22,647,688, 4 genes, copy number 8: CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P.
- chr20:47,209,214–64,313,132, 412 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr22:29,073,035–30,505,711, 67 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr22:34,589,085–40,636,719, 220 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr22:41,244,779–42,787,100, 72 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,107. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
